Gene-level copy-number profile of tumor specimen ALCH-B2P7-TTP1-A from ALCHEMIST case ALCH-B2P7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.4 years (21,678 days).
Specimen ALCH-B2P7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f6a672e0-95eb-4871-aa69-42487897ba6a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2P7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/bdbc6b2c-0e19-4acd-a789-c95202fc0dce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 9,252; copy number 2: 43,513; copy number 3: 5,284; copy number 4: 260; copy number 5: 18; copy number 6: 5; copy number 7: 3; copy number 8: 2; copy number 11: 5.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,292,390–1,361,777, 11 genes: ACAP3, MIR6726, PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3, DVL1, MIR6808, MXRA8.
- chr1:143,745,249–143,769,083, 2 genes: AC239800.1, FAM91A3P.
- chr2:89,319,625–89,320,146, 1 gene: IGKV1-39.
- chr2:90,100,236–90,100,738, 1 gene: IGKV1D-16.
- chr2:90,359,809–91,580,863, 4 genes: AC233263.1, AC233263.7, AC233266.1, AC233266.2.
- chr3:55,335,462–55,350,915, 1 gene: AC121764.2.
- chr4:49,502,145–49,508,806, 2 genes: ANKRD20A17P, AC119751.5.
- chr9:68,328,308–68,531,061, 4 genes (within-gene range 0–1): PGM5, PGM5-AS1, AL161457.2, AL161457.1.
- chr10:26,717,635–26,718,778, 1 gene (within-gene range 0–2): AL390961.2.
- chr11:1,983,237–1,989,920, 1 gene (within-gene range 0–5): MRPL23-AS1.
- chr14:105,526,583–105,530,202, 1 gene: TMEM121.
- chr16:991,151–1,000,926, 1 gene: AC009041.1.
- chr16:1,065,240–1,066,502, 1 gene (within-gene range 0–1): AC009041.2.
- chr19:15,010,726–15,092,970, 3 genes (within-gene range 0–1): CCDC105, CASP14, OR1I1.
- chr19:35,143,250–35,169,881, 2 genes (within-gene range 0–2): FXYD7, FXYD5.
- chr19:52,511,282–52,512,342, 1 gene (within-gene range 0–2): AC022150.3.
- chr21:12,999,676–13,120,807, 5 genes: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:18,527,802–18,530,573, 1 gene: TMEM191B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:185,426,249–185,449,826, 1 gene, copy number 5 (within-gene range 2–5): C4orf47.
- chr6:32,517,353–32,589,848, 4 genes, copy number 6: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr10:68,698,500–68,700,794, 1 gene, copy number 5: AL513534.2.
- chr11:1,947,278–1,984,522, 1 gene, copy number 5 (within-gene range 0–5): MRPL23.
- chr11:1,991,096–2,001,470, 5 genes, copy number 11: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr11:48,880,111–48,983,826, 7 genes, copy number 5: AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2, TRIM51GP.
- chr11:55,262,155–55,271,114, 2 genes, copy number 5: TRIM48, AP005597.4.
- chr13:112,313,467–112,331,225, 2 genes, copy number 5: LINC01043, LINC01044.
- chr14:64,704,102–64,750,249, 1 gene, copy number 5 (within-gene range 2–5): PLEKHG3.
- chr17:18,476,737–18,494,945, 1 gene, copy number 6: LGALS9C.
- chr21:43,414,483–43,479,534, 4 genes, copy number 7–8 (within-gene range 7–12): SIK1, LINC00319, LINC00313, AP001048.1.
- chr22:18,361,820–18,391,105, 2 genes, copy number 5: FAM230J, AC011718.1.
- chr22:18,533,646–18,577,968, 1 gene, copy number 7: PI4KAP1.
- chr22:18,733,914–18,757,906, 1 gene, copy number 5: FAM230E.

Autosomal genes at a single copy (total copy number 1): 9,235. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
